TCGA case TCGA-95-A4VK — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - Emory. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d344dae0-adf4-4697-b703-7690c13d8331

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 74.0 years (27,040 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed Disodium; Days to treatment start: 76 days; Days to treatment end: 121 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 202 days; Days to treatment end: 202 days; Treatment dose: 50 Gy; Treatment outcome: Stable Disease; Number of fractions: 28; Treatment anatomic sites: Regional Site.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Thorax, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 67.9 years (24,818 days); Days to diagnosis: -2,222 days (-6.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,233 days (-6.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 75.4 years (27,536 days); Days to diagnosis: 496 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 121 days; Disease response: Tumor Free.
- Day 496 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 496 days (1.4 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 651 days (1.8 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 81; FEV1/FVC after bronchodilator (%): 72; FEV1/FVC before bronchodilator (%): 67; FEV1 after bronchodilator (% of reference): 99; FEV1 before bronchodilator (% of reference): 99.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 45; Tobacco smoking onset year: 1956; Tobacco smoking quit year: 1986.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-95-A4VK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-95-A4VK-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-95-A4VK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-95-A4VK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: Yes; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Chest; Other malignancy histological type: Melanoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Removal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 651 days; disease-specific survival: no event (censored), 651 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 496 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-95-A4VK-01A-11D-A25M-01): tumor purity 0.57, ploidy 2.02, whole-genome doublings 0.
